Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A780, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A780-01A (Primary Tumor).

ICD-O-3

Astrocytoma, grade III
Site Brain, supratentorial NOS
path
② Brain, frontal lobe
9401/3
C71.0
C71.1
8/20/13

Case #

Patient: Age (years): Gender: Female

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by dense gray pieces from right frontal lobe

Microscopic description:

Received material is represented by brain tissue fragments with diffuse astrocytoma. Nuclear polymorphism; Ki67 > 5%

Final diagnosis: Diffuse astrocytoma Grade II advancing to Grade III

Confidential

Source: NCI Genomic Data Commons file 85261472-d2a0-456c-b0e5-0779f708a0ae (TCGA-P5-A780.6EBF635A-6875-4843-815A-3E4E25B61BA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).